Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WO, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WO-01A (Primary Tumor).

ICD-O-3
Astrocytoma, grade II
9400/3
Site Brain, supratentorial NOS
C71.0
QW 8/12/13

Translation

diffuse astrocytic tumor with low proliferation.

IDH1 mutation.

Diagnosis:

astrocytoma WHO grade II

Untranslated full report is
hosted at the BCR.

Source: NCI Genomic Data Commons file 202153a1-1cf3-4999-ac23-71fa6dcf2a58 (TCGA-S9-A6WO.BA4CC860-7E94-4CC5-B9E0-F3340749C71C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).